TCGA case TCGA-F5-6810 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/375436b3-66ac-4d5e-b495-18a96d812a69

Demographics
Country of residence at enrollment: Russia.

Diagnoses (1)
1. Primary (histology not recorded by GDC). Prior malignancy: no; Synchronous malignancy: No.
   Pathology details: Consistent pathology review: Yes.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-F5-6810-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 3.3; Intermediate dimension: 1.2; Shortest dimension: 0.6.
  Slide TCGA-F5-6810-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 20; Percent necrosis: 5; Percent lymphocyte infiltration: 10; Percent neutrophil infiltration: 2.
  Slide TCGA-F5-6810-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 20; Percent necrosis: 5; Percent lymphocyte infiltration: 10; Percent neutrophil infiltration: 3.
- Sample TCGA-F5-6810-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-F5-6810-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-F5-6810-01A-11D-1825-01): tumor purity 0.65, ploidy 3.45, whole-genome doublings 1.
